Gene-level copy-number profile of tumor specimen C3L-05229-01 from CPTAC case C3L-05229, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 82.3 years (30,074 days).
Specimen C3L-05229-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c627fb78-a42f-4425-b934-5b081e091163.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05229-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/1779e454-e77a-456f-9e06-f9f4d6985ff7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 14,452; copy number 2: 37,546; copy number 3: 5,322; copy number 4: 1,122; copy number 5: 461.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 461 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:30,798,654–31,593,006, 73 genes, copy number 5 (broad region; genes not listed).
- chr6:33,004,182–33,329,286, 33 genes, copy number 5: HLA-DOA, HLA-DPA1, HLA-DPB1, RPL32P1, HLA-DPA2, COL11A2P1, HLA-DPB2, HLA-DPA3, HCG24, COL11A2, RXRB, RNY4P10, SLC39A7, HSD17B8, MIR219A1, RING1, ZNF70P1, HTATSF1P1, AL645940.1, HCG25, VPS52, RPS18, B3GALT4, WDR46, MIR6873, PFDN6, MIR6834, RGL2, TAPBP, ZBTB22, DAXX, SMIM40, SMIM40.
- chr6:34,018,643–36,111,236, 62 genes, copy number 5 (broad region; genes not listed).
- chr6:36,940,071–43,075,095, 149 genes, copy number 5 (broad region; genes not listed).
- chr6:44,113,451–44,265,788, 10 genes, copy number 5: MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE.
- chr6:44,273,194–44,378,957, 1 gene, copy number 5 (within-gene range 3–5): AL353588.1.
- chr6:44,298,731–44,380,179, 2 genes, copy number 5 (within-gene range 3–5): AARS2, SPATS1.
- chr6:45,328,157–45,664,349, 3 genes, copy number 5 (within-gene range 3–5): RUNX2, AL096865.1, RUNX2-AS1.
- chr12:92,702,843–92,929,331, 4 genes, copy number 5: PLEKHG7, EEA1, AC026111.1, HNRNPA1P50.
- chr15:84,053,113–85,330,334, 54 genes, copy number 5: AC027807.1, EFL1P1, DNM1P41, AC136698.1, UBE2Q2L, CSPG4P11, GOLGA2P7, RN7SL331P, GOLGA6L4, UBE2Q2P8, AC243562.2, RN7SL417P, AC243562.1, DNM1P51, CSPG4P5, UBE2Q2P11, AC243562.3, Metazoa_SRP, UBE2Q2P12, AC048382.4, AC048382.3, GOLGA6L5P, AC048382.2, UBE2Q2P1, LINC00933, AC048382.5, ZSCAN2, AC048382.1, AC048382.6, SCAND2P, EGLN1P1, WDR73, Metazoa_SRP, NMB, SEC11A, AC115102.1, ZNF592, AC012291.2, ALPK3, AC012291.1, SLC28A1, AC087468.2, RNU6-339P, RNU6-796P, AC087468.1, PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3.
- chr18:4,775,054–5,989,369, 21 genes, copy number 5 (within-gene range 4–5): AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1, EPB41L3, AP005059.2, AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1.
- chr18:11,609,596–12,658,134, 49 genes, copy number 5 (within-gene range 4–5): SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, AP001120.1, GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1, PMM2P2, AP005264.5, AP005264.3, AP005264.4, CCDC58P3, AP005264.2, PPIAP56, CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1, AP001029.3.

Autosomal genes at a single copy (total copy number 1): 11,596. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
